Gene-level copy-number profile of tumor specimen TCGA-49-6761-01A from TCGA case TCGA-49-6761, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 68.0 years (24,849 days).
Specimen TCGA-49-6761-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.98b2eac9-d712-4d03-947f-84c9d8df246f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-49-6761-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5c635f7d-5712-417e-b414-c0542b1ac798

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,644; copy number 2: 18,958; copy number 3: 29,260; copy number 4: 2,991; copy number 5: 3,033; copy number 6: 344; copy number 7: 686; copy number 8: 1,730; copy number 9: 1,091; copy number 13: 83.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-49-6761-01A-31D-1943-01): tumor purity 0.29, ploidy 3.19, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,590 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–162,370,475, 859 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr7:70,972–63,263,456, 1,091 genes, copy number 9 (broad region; genes not listed).
- chr8:49,740,216–145,066,685, 1,466 genes, copy number 8 (broad region; genes not listed).
- chr14:25,916,015–36,679,362, 174 genes, copy number 8–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 861. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
